Somatic mutation profile of tumor specimen MMRF_1283_1_BM_CD138pos (aliquot MMRF_1283_1_BM_CD138pos_T1_KBS5U_L05375) from MMRF case MMRF_1283, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: female; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 65.6 years (23,943 days).
Specimen MMRF_1283_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c879ceb2-b353-4655-9927-d1266ec7c049.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_1283_1_PB_Whole (Blood Derived Normal), aliquot MMRF_1283_1_PB_Whole_C2_KBS5U_L05387; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c5352c60-4de5-45b2-bc7a-51c13a4b22d7

The open-access MAF lists 106 somatic variants for this specimen: 47 protein-altering or splice-affecting, 12 silent, 47 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 40, 3'UTR 21, Silent 12, Intron 11, 5'Flank 5, Frame Shift Del 4, RNA 4, 5'UTR 4, 3'Flank 2, Splice Site 1, Splice Region 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.183A>C p.Q61H | Missense Mutation (SNP) | VAF 18/51 reads (35%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.121); catalogued as rs17851045, COSV55498802, COSV55499223, COSV55811221; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- BOD1L2 | c.22G>A p.G8S | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated, low confidence (0.85); PolyPhen possibly damaging (0.601); catalogued as rs1395258895; called by muse, mutect2, varscan2
- CARMIL3 | c.676C>T p.R226W | Missense Mutation (SNP) | VAF 40/126 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs763740276, COSV57727014; called by muse, mutect2, varscan2
- DNTTIP1 | c.823C>T p.R275W | Missense Mutation (SNP) | VAF 19/86 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.827); catalogued as rs752890673, COSV54754981; called by muse, mutect2, varscan2
- EP400 | c.191G>C p.R64T | Missense Mutation (SNP) | VAF 39/76 reads (51%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs1426175120; called by muse, mutect2, varscan2
- EPHB3 | c.1319G>A p.R440H | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as rs370732996, COSV57809123; called by muse, mutect2, varscan2
- FAT4 | c.13208C>T p.P4403L | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs755945513, COSV100627375; called by muse, mutect2, varscan2
- MARK2 | c.2235C>A p.F745L (on ENST00000402010 / NM_001039469.2; = p.F681L on NM_004954.5) | Missense Mutation (SNP) | VAF 6/138 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV56851636; called by muse, mutect2
- NCAPD2 | c.4031G>A p.R1344H | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT tolerated (0.05); PolyPhen benign (0); catalogued as rs760736035, COSV57520758; called by muse, mutect2, varscan2
- NRG2 | c.1060G>A p.V354I | Missense Mutation (SNP) | VAF 37/140 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.301); catalogued as rs1051519654; called by muse, mutect2, varscan2
- OR5L1 | c.878G>A p.R293K | Missense Mutation (SNP) | VAF 52/181 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.624); catalogued as COSV61733546; called by muse, mutect2, varscan2
- PLB1 | c.2305C>T p.R769W | Missense Mutation (SNP) | VAF 29/55 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs370932074; called by muse, mutect2, varscan2
- POMGNT1 | c.644G>A p.R215Q | Missense Mutation (SNP) | VAF 15/40 reads (38%) | PolyPhen benign (0); catalogued as rs770634205, COSV100915725, COSV64340365; called by muse, mutect2, varscan2
- PTPA | c.121C>T p.R41C | Missense Mutation (SNP) | VAF 15/191 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.892); catalogued as rs200345986; called by muse, mutect2
- RBM6 | c.2354-2A>G p.X785_splice | Splice Site (SNP) | VAF 40/118 reads (34%) | catalogued as rs112825789; called by muse, mutect2, varscan2
- TDRD6 | c.454G>A p.A152T | Missense Mutation (SNP) | VAF 30/67 reads (45%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs1408955390, COSV60177419; called by muse, mutect2, varscan2
- TNFRSF11A | c.1460C>T p.T487M | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as rs751561139, COSV54024910; called by mutect2, varscan2
- TNS2 | c.1762C>T p.L588F (on ENST00000314250 / NM_170754.4; = p.L598F on NM_015319.2) | Missense Mutation (SNP) | VAF 28/70 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); catalogued as COSV58576835; called by muse, mutect2, varscan2
- VANGL1 | c.518G>A p.R173H | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs148341022, CM127311; ClinVar: benign; called by muse, mutect2, varscan2
- ZFPM2 | c.2138G>A p.R713H | Missense Mutation (SNP) | VAF 42/75 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1294441553, COSV65872389; called by muse, mutect2, varscan2
- ZNF529 | c.1148G>A p.R383H | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.957); catalogued as rs568515212, COSV61899845, COSV61901686; called by muse, mutect2, varscan2
- ZNF582 | c.549G>T p.K183N | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT tolerated (0.47); PolyPhen benign (0.017); catalogued as COSV56732254; called by muse, mutect2, varscan2
- A1CF | c.410G>T p.R137L | Missense Mutation (SNP) | VAF 34/98 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.517); called by muse, mutect2, varscan2
- AATK | c.1136G>T p.W379L (on ENST00000326724 / NM_001080395.3; = p.W276L on NM_004920.2) | Missense Mutation (SNP) | VAF 5/60 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.083); called by muse, mutect2
- ADGRE2 | c.2260C>G p.P754A | Missense Mutation (SNP) | VAF 10/118 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.909); called by muse, mutect2
- ATP10A | c.2003A>G p.N668S | Missense Mutation (SNP) | VAF 23/85 reads (27%) | SIFT tolerated (0.39); PolyPhen benign (0.082); called by muse, mutect2, varscan2
- CHM | c.58G>A p.E20K | Missense Mutation (SNP) | VAF 101/128 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DNAH14 | c.1397del p.K466Rfs*42 (on ENST00000445597; = p.K447Rfs*12 on NM_001145154.3) | Frame Shift Del (DEL) | VAF 10/22 reads (45%) | called by mutect2, varscan2
- DSCAM | c.1681C>T p.L561F | Missense Mutation (SNP) | VAF 24/63 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- F5 | c.2204G>T p.G735V | Missense Mutation (SNP) | VAF 16/170 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2
- FAM120B | c.1454T>G p.V485G | Missense Mutation (SNP) | VAF 80/192 reads (42%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.634); called by muse, mutect2, varscan2
- FMO3 | c.548A>G p.N183S | Missense Mutation (SNP) | VAF 46/90 reads (51%) | SIFT tolerated (0.26); PolyPhen benign (0); called by muse, mutect2, varscan2
- GSDMA | c.801_802dup p.T268Rfs*8 | Frame Shift Ins (INS) | VAF 36/91 reads (40%) | called by mutect2, varscan2
- H1-3 | c.323_327del p.L108Qfs*21 | Frame Shift Del (DEL) | VAF 15/43 reads (35%) | called by mutect2, pindel, varscan2
- HENMT1 | c.414_418del p.D138Efs*2 | Frame Shift Del (DEL) | VAF 54/123 reads (44%) | called by mutect2, pindel, varscan2
- ISLR2 | c.886G>T p.G296W | Missense Mutation (SNP) | VAF 50/109 reads (46%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.552); called by muse, mutect2, varscan2
- JPH4 | c.802G>A p.A268T | Missense Mutation (SNP) | VAF 15/28 reads (54%) | SIFT tolerated (0.43); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- KCNH5 | c.2341G>T p.A781S | Missense Mutation (SNP) | VAF 75/273 reads (27%) | SIFT tolerated, low confidence (0.71); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- LZTS3 | c.1145C>T p.A382V | Missense Mutation (SNP) | VAF 18/37 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- MACF1 | c.689A>T p.N230I | Missense Mutation (SNP) | VAF 14/53 reads (26%) | called by muse, mutect2, varscan2
- MOSPD1 | c.101A>C p.H34P | Missense Mutation (SNP) | VAF 46/117 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- MROH2B | c.616-6G>T | Splice Region (SNP) | VAF 18/63 reads (29%) | called by muse, mutect2, varscan2
- MYO16 | c.2731G>C p.V911L | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.336); called by muse, mutect2, varscan2
- PUM2 | c.2970A>T p.L990F | Missense Mutation (SNP) | VAF 25/60 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- RBM10 | c.1004A>T p.K335M | Missense Mutation (SNP) | VAF 53/61 reads (87%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); called by muse, mutect2, varscan2
- SLIT2 | c.1517G>T p.C506F | Missense Mutation (SNP) | VAF 28/70 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TTN | c.100412_100426delinsG p.K33471Rfs*35 (on ENST00000591111; = p.K26047Rfs*35 on NM_003319.4) | Frame Shift Del (DEL) | VAF 34/117 reads (29%) | called by pindel, varscan2*
- DHRS2 | c.573G>A p.A191= | Silent (SNP) | VAF 17/54 reads (31%) | catalogued as rs186440699, COSV99160857; called by muse, mutect2, varscan2
- DNMT3A | c.273G>C p.G91= | Silent (SNP) | VAF 10/90 reads (11%) | catalogued as COSV53086647; called by muse, mutect2, varscan2
- GPR35 | c.366G>A p.L122= | Silent (SNP) | VAF 12/35 reads (34%) | called by muse, mutect2, varscan2
- GZF1 | c.948C>T p.N316= | Silent (SNP) | VAF 28/141 reads (20%) | catalogued as rs962198430, COSV57634897; called by muse, mutect2, varscan2
- IGHJ4 | c.45A>C p.S15= | Silent (SNP) | VAF 58/103 reads (56%) | catalogued as rs141539541; called by muse, varscan2
- IGHV2-70 | c.84T>C p.P28= | Silent (SNP) | VAF 58/95 reads (61%) | catalogued as rs377604349; called by muse, varscan2
- MAT1A | c.1074C>T p.G358= | Silent (SNP) | VAF 69/155 reads (45%) | catalogued as rs373567910; called by muse, mutect2, varscan2
- PCK1 | c.708C>T p.G236= | Silent (SNP) | VAF 37/100 reads (37%) | catalogued as rs768241848, COSV60127838; called by muse, mutect2, varscan2
- PEX7 | c.495C>G p.P165= | Silent (SNP) | VAF 33/94 reads (35%) | called by muse, mutect2, varscan2
- RNF222 | c.492C>T p.S164= | Silent (SNP) | VAF 13/46 reads (28%) | catalogued as rs968209150; called by muse, mutect2, varscan2
- SPHKAP | c.2970C>T p.T990= | Silent (SNP) | VAF 54/112 reads (48%) | catalogued as rs958351498; called by muse, mutect2, varscan2
- SYNPO | c.2538G>A p.L846= (on ENST00000394243 / NM_001166208.2; = p.L602= on NM_007286.6) | Silent (SNP) | VAF 59/209 reads (28%) | catalogued as rs756417270; called by muse, mutect2, varscan2
- AC078899.1 | n.962T>A | RNA (SNP) | VAF 72/197 reads (37%) | called by muse, mutect2, varscan2
- AHI1 | c.*431G>A | 3'UTR (SNP) | VAF 4/14 reads (29%) | called by muse, mutect2
- ANKMY2 | c.*677T>C | 3'UTR (SNP) | VAF 6/80 reads (8%) | catalogued as rs1007765885; called by muse, mutect2
- B3GNT7 | c.*286G>A | 3'UTR (SNP) | VAF 3/46 reads (7%) | catalogued as rs1031759741; called by muse, mutect2
- CACNG2 | c.-1036C>T | 5'UTR (SNP) | VAF 3/23 reads (13%) | called by muse, mutect2
- CHRD | c.2196+38C>A | Intron (SNP) | VAF 26/106 reads (25%) | called by muse, mutect2, varscan2
- CLEC3A | c.*625dup | 3'UTR (INS) | VAF 9/44 reads (20%) | catalogued as rs568788303; called by mutect2, pindel*, varscan2
- CNN3 | c.*718G>A | 3'UTR (SNP) | VAF 30/58 reads (52%) | called by muse, mutect2, varscan2
- CXXC4 | c.*126G>T | 3'UTR (SNP) | VAF 22/61 reads (36%) | catalogued as rs1560537621; called by muse, mutect2, varscan2
- EI24 | c.*289A>G | 3'UTR (SNP) | VAF 12/334 reads (4%) | catalogued as rs1404365430; called by muse, mutect2
- ELP1 | c.2587+54C>G | Intron (SNP) | VAF 4/53 reads (8%) | catalogued as rs1322808220; called by muse, mutect2
- FYB1 | c.*1819C>A | 3'UTR (SNP) | VAF 20/59 reads (34%) | called by muse, mutect2, varscan2
- GASK1B | c.*1843T>C | 3'UTR (SNP) | VAF 22/44 reads (50%) | called by muse, mutect2, varscan2
- GLRA4 | c.-9C>A | 5'UTR (SNP) | VAF 139/158 reads (88%) | called by muse, mutect2, varscan2
- HECA | c.*3028A>G | 3'UTR (SNP) | VAF 4/66 reads (6%) | called by muse, mutect2
- HSPH1 | chr13:31162225 A>C | 5'Flank (SNP) | VAF 4/12 reads (33%) | called by muse, mutect2, varscan2
- IFT43 | c.295+119G>A | Intron (SNP) | VAF 4/20 reads (20%) | called by muse, mutect2, varscan2
- IHO1 | chr3:49260438 A>C | 3'Flank (SNP) | VAF 97/166 reads (58%) | called by muse, mutect2, varscan2
- IL21R | c.*1703G>C | 3'UTR (SNP) | VAF 31/70 reads (44%) | called by muse, mutect2, varscan2
- ITPR1 | c.5197-874G>T | Intron (SNP) | VAF 7/19 reads (37%) | called by muse, mutect2, varscan2
- KDM4B | c.627-36C>T | Intron (SNP) | VAF 40/128 reads (31%) | catalogued as rs759249293; called by muse, mutect2, varscan2
- KIAA1143 | c.*998C>T | 3'UTR (SNP) | VAF 51/104 reads (49%) | catalogued as rs1034226573; called by muse, mutect2, varscan2
- MAN2B2 | c.2815-242C>T | Intron (SNP) | VAF 50/107 reads (47%) | catalogued as rs1055060380; called by muse, mutect2, varscan2
- MEOX1 | c.*1409T>A | 3'UTR (SNP) | VAF 11/32 reads (34%) | called by muse, mutect2, varscan2
- NLGN2 | c.*593C>T | 3'UTR (SNP) | VAF 32/124 reads (26%) | catalogued as rs936806581; called by muse, mutect2, varscan2
- NR4A1 | c.160+1949del | Intron (DEL) | VAF 5/42 reads (12%) | catalogued as rs1177213701; called by mutect2, pindel, varscan2
- OR5F2P | n.235C>T | RNA (SNP) | VAF 27/100 reads (27%) | called by muse, mutect2, varscan2
- PLAAT5 | chr11:63462695 G>A | 3'Flank (SNP) | VAF 35/108 reads (32%) | called by muse, mutect2, varscan2
- PLXND1 | c.*908C>T | 3'UTR (SNP) | VAF 19/47 reads (40%) | catalogued as rs908478731; called by muse, mutect2, varscan2
- PPAT | c.*1923C>G | 3'UTR (SNP) | VAF 65/155 reads (42%) | called by muse, mutect2, varscan2
- PPL | c.1395-63C>T | Intron (SNP) | VAF 10/26 reads (38%) | called by muse, mutect2
- PRKRIP1 | chr7:102396210 G>A | 5'Flank (SNP) | VAF 50/159 reads (31%) | called by muse, mutect2, varscan2
- PTGER3 | c.1077+5495C>A | Intron (SNP) | VAF 18/45 reads (40%) | called by muse, mutect2
- PTPRT | c.*4724C>T | 3'UTR (SNP) | VAF 21/54 reads (39%) | catalogued as rs868779281; called by muse, mutect2, varscan2
- RANBP1 | chr22:20115994 G>A | 5'Flank (SNP) | VAF 32/68 reads (47%) | catalogued as rs368959954; called by muse, mutect2, varscan2
- ROBO1 | c.1046-4572A>T | Intron (SNP) | VAF 26/109 reads (24%) | catalogued as rs1413103865; called by muse, mutect2, varscan2
- ROR1 | c.1174+215G>A | Intron (SNP) | VAF 3/40 reads (8%) | called by muse, mutect2
- SHC3 | c.-60G>T | 5'UTR (SNP) | VAF 38/112 reads (34%) | called by muse, mutect2, varscan2
- SHOC1 | chr9:111785980 C>T | 5'Flank (SNP) | VAF 18/69 reads (26%) | called by muse, mutect2, varscan2
- TNRC18P2 | n.1633G>A | RNA (SNP) | VAF 8/36 reads (22%) | called by muse, mutect2
- TXNDC5 | c.*831C>G | 3'UTR (SNP) | VAF 31/83 reads (37%) | called by muse, mutect2, varscan2
- VN1R6P | n.524A>T | RNA (SNP) | VAF 41/164 reads (25%) | called by muse, mutect2, varscan2
- VPS13C | c.*1344dup | 3'UTR (INS) | VAF 42/74 reads (57%) | catalogued as rs896023226; called by mutect2, varscan2
- YAP1 | c.*1829A>C | 3'UTR (SNP) | VAF 12/49 reads (24%) | called by muse, mutect2, varscan2
- ZBTB37 | chr1:173866096 del C | 5'Flank (DEL) | VAF 21/53 reads (40%) | called by mutect2, pindel, varscan2
- ZNF232 | c.-502T>G | 5'UTR (SNP) | VAF 29/52 reads (56%) | called by muse, mutect2, varscan2
- ZNF662 | c.*1399dup | 3'UTR (INS) | VAF 15/63 reads (24%) | catalogued as rs1439289129; called by mutect2, varscan2
